Somatic mutation profile of tumor specimen C3N-02005-01 (aliquot CPT0109770007) from CPTAC case C3N-02005, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.2 years (23,084 days).
Specimen C3N-02005-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ca27760-7c3e-4fc7-8f06-8507c15e2a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02005-71 (Blood Derived Normal), aliquot CPT0139310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/858047ca-3fbb-4681-9a57-8827891854c4

The open-access MAF lists 421 somatic variants for this specimen: 295 protein-altering or splice-affecting, 71 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 237, Silent 71, Nonsense Mutation 24, Intron 21, RNA 15, Splice Site 13, Frame Shift Del 13, 3'UTR 7, 5'UTR 5, 3'Flank 5, Frame Shift Ins 4, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 104/377 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- ABCB1 | c.3644A>T p.Q1215L | Missense Mutation (SNP) | VAF 213/702 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55950357; called by muse, mutect2, varscan2
- ADGRL2 | c.1978A>G p.R660G (on ENST00000370717 / NM_001366005.1; = p.R647G on NM_012302.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.41); catalogued as rs1255275174; called by muse, mutect2
- ALS2 | c.2710A>T p.T904S | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs764566405; called by muse, mutect2, varscan2
- ASS1 | c.689-2A>T p.X230_splice | Splice Site (SNP) | VAF 144/490 reads (29%) | catalogued as rs374586230; called by muse, mutect2, varscan2
- ATP10A | c.2009A>T p.Y670F | Missense Mutation (SNP) | VAF 142/470 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV63521882; called by muse, mutect2, varscan2
- C11orf91 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.438); catalogued as rs894323382; called by muse, mutect2, varscan2
- C2CD6 | c.262A>T p.S88C | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99632332; called by muse, mutect2, varscan2
- CA1 | c.39T>C p.G13= | Splice Region (SNP) | VAF 131/413 reads (32%) | catalogued as rs777306238; called by muse, mutect2, varscan2
- CCDC154 | c.1740G>T p.W580C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1347836611; called by muse, mutect2, varscan2
- CNTNAP4 | c.3316A>G p.I1106V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770637612, COSV56672591; called by muse, mutect2, varscan2
- INSIG2 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs913313376; called by muse, mutect2, varscan2
- KCNC2 | c.1367T>A p.L456Q | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54374843; called by muse, mutect2, varscan2
- KLHL12 | c.1273A>T p.S425C | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV66128062; called by muse, mutect2, varscan2
- KLHL33 | c.476T>A p.L159Q | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1374949287; called by muse, mutect2, varscan2
- KMT2E | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1234381772, COSV57570148; called by muse, mutect2, varscan2
- LRFN5 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 97/323 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV53268976; called by muse, mutect2, varscan2
- MKI67 | c.5222A>T p.Q1741L | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.322); catalogued as rs1193317021; called by muse, mutect2, varscan2
- NDNF | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV65634498; called by muse, mutect2, varscan2
- NME5 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759175099; called by muse, mutect2, varscan2
- PAX5 | c.287T>C p.V96A | Missense Mutation (SNP) | VAF 76/325 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100814326; called by muse, mutect2, varscan2
- PCDHGA7 | c.1401A>T p.R467S | Missense Mutation (SNP) | VAF 65/212 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.833); catalogued as COSV53899504; called by muse, mutect2, varscan2
- PDE4D | c.1664C>T p.T555I (on ENST00000340635 / NM_001104631.2; = p.T419I on NM_006203.4) | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.59); catalogued as COSV57721292; called by muse, mutect2, varscan2
- PDZRN4 | c.145A>T p.R49W | Missense Mutation (SNP) | VAF 176/498 reads (35%) | SIFT tolerated, low confidence (0.23); catalogued as rs770664116; called by muse, mutect2, varscan2
- PEAK1 | c.926A>C p.Y309S | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56932040; called by muse, mutect2, varscan2
- PPP1R16B | c.1186A>T p.K396* | Nonsense Mutation (SNP) | VAF 83/217 reads (38%) | catalogued as COSV55377846; called by muse, mutect2, varscan2
- PRKDC | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1474338260; called by muse, mutect2, varscan2
- PSG5 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.439); catalogued as rs139513452; called by muse, mutect2, varscan2
- RHCE | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as CM135198; called by muse, mutect2, varscan2
- RUSC1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.288); catalogued as rs769555069; called by muse, mutect2, varscan2
- SCN10A | c.3571A>T p.R1191W | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773662455; called by muse, mutect2, varscan2
- SCN1A | c.4405T>A p.F1469I (on ENST00000303395 / NM_001202435.3; = p.F1458I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57660132; called by muse, mutect2, varscan2
- SCNN1G | c.1787T>A p.L596Q | Missense Mutation (SNP) | VAF 114/390 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs972234433; called by muse, mutect2, varscan2
- SEC14L1 | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs757317007, COSV101170841; called by muse, mutect2, varscan2
- SETD2 | c.2947G>T p.E983* | Nonsense Mutation (SNP) | VAF 49/112 reads (44%) | catalogued as COSV100339032, COSV57448366; called by muse, mutect2, varscan2
- SIGLEC10 | c.1797T>A p.N599K | Missense Mutation (SNP) | VAF 68/264 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs202023625, COSV59482264; called by muse, mutect2, varscan2
- SLC6A2 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 196/594 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54915112; called by muse, varscan2
- SMARCA4 | c.4082A>T p.E1361V | Missense Mutation (SNP) | VAF 153/508 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV100758082; called by mutect2, varscan2
- SORCS1 | c.2687C>G p.S896C | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1362528668; called by muse, mutect2, varscan2
- SPATA17 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 85/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV65119495; called by muse, mutect2, varscan2
- SYNPO2L | c.2678C>T p.P893L (on ENST00000394810 / NM_001114133.3; = p.P669L on NM_024875.5) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1007192278; called by muse, mutect2, varscan2
- TENM2 | c.2354G>A p.C785Y (on ENST00000518659 / NM_001122679.2; = p.C553Y on NM_001080428.3) | Missense Mutation (SNP) | VAF 115/421 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1401129472; called by muse, mutect2, varscan2
- THG1L | c.644A>T p.D215V | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99180299; called by muse, mutect2
- TNFSF13B | c.595-2A>T p.X199_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as rs778494632; called by muse, mutect2, varscan2
- TNRC6C | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV100049662; called by muse, mutect2, varscan2
- TPPP | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 121/314 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs147824661; called by muse, mutect2, varscan2
- TRPM5 | c.714+2T>A p.X238_splice | Splice Site (SNP) | VAF 39/136 reads (29%) | catalogued as COSV99030413; called by muse, mutect2, varscan2
- TSHZ3 | c.1255A>G p.M419V | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs754464209; called by muse, mutect2, varscan2
- VGLL2 | c.33T>A p.Y11* | Nonsense Mutation (SNP) | VAF 90/311 reads (29%) | catalogued as COSV104397904; called by muse, mutect2, varscan2
- VHL | c.405_406dup p.F136Yfs*24 | Frame Shift Ins (INS) | VAF 84/256 reads (33%) | catalogued as COSV56553005; called by mutect2, pindel, varscan2
- ZNF136 | c.580A>T p.T194S | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.214); catalogued as COSV59710829; called by muse, mutect2, varscan2
- ZNF728 | c.853A>T p.K285* | Nonsense Mutation (SNP) | VAF 89/356 reads (25%) | catalogued as COSV104441859; called by muse, mutect2, varscan2
- ABCB11 | c.488G>T p.W163L | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM4 | c.1211T>A p.I404K | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- ADAM29 | c.2029T>A p.C677S | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS1 | c.1346A>T p.Y449F | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ADAMTS15 | c.1885T>A p.Y629N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- ADAMTS4 | c.1871A>T p.Q624L | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, mutect2
- AHI1 | c.1345-2A>C p.X449_splice | Splice Site (SNP) | VAF 51/175 reads (29%) | called by muse, mutect2, varscan2
- AHNAK | c.15347A>T p.E5116V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AHNAK | c.15346G>T p.E5116* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- AIRE | c.1401-2A>T p.X467_splice | Splice Site (SNP) | VAF 47/194 reads (24%) | called by muse, mutect2
- AKAP9 | c.7377A>T p.R2459S (on ENST00000359028; = p.R2435S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- AL121899.2 | c.388T>A p.Y130N | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOXE3 | c.1300T>A p.Y434N | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ANKRD30A | c.197T>A p.L66H (on ENST00000611781; = p.L10H on NM_052997.2) | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD30B | c.104A>T p.Y35F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO2 | c.886del p.I296Lfs*4 (on ENST00000356134 / NM_001278597.3; = p.I300Lfs*4 on NM_001278596.3) | Frame Shift Del (DEL) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- AP3M1 | c.490A>T p.N164Y | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- ARHGEF38 | c.586A>T p.S196C | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ASCC2 | c.1748A>T p.Q583L | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ASPG | c.1316A>G p.H439R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPN | c.649T>G p.F217V | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATG2B | c.911T>G p.L304R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- B3GAT2 | c.923del p.L308Qfs*12 | Frame Shift Del (DEL) | VAF 60/250 reads (24%) | called by mutect2, pindel
- B4GALT4 | c.720A>T p.R240S | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- BAZ2B | c.3349A>T p.N1117Y | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- BRD2 | c.2009A>T p.Q670L | Missense Mutation (SNP) | VAF 165/472 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- BTN1A1 | c.1139T>A p.M380K | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C1orf141 | c.74A>T p.K25M | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC134 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 98/314 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CCDC158 | c.2472A>T p.Q824H | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC168 | c.7136T>C p.I2379T | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CDK17 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- CFAP65 | c.3029A>T p.Q1010L | Missense Mutation (SNP) | VAF 74/246 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CFAP74 | c.1206T>A p.F402L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHKB | c.46_48del p.G16del | In Frame Del (DEL) | VAF 126/414 reads (30%) | called by pindel, varscan2
- CHML | c.1043A>T p.E348V | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CIZ1 | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CNGB1 | c.98T>A p.M33K | Missense Mutation (SNP) | VAF 165/552 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNN2 | c.284T>A p.M95K | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CNTN1 | c.2399T>A p.V800D | Missense Mutation (SNP) | VAF 112/345 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- COL4A6 | c.4402T>A p.Y1468N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- COL6A3 | c.3242A>T p.Y1081F | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CPA2 | c.955A>C p.K319Q | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, varscan2
- CPXCR1 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CR1 | c.2608T>A p.F870I | Missense Mutation (SNP) | VAF 75/292 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CRX | c.557T>A p.L186Q | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CSF3R | c.2021T>A p.V674E | Missense Mutation (SNP) | VAF 114/473 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CSMD2 | c.9023A>T p.K3008I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTIF | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- CUX2 | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DCN | c.590A>T p.Q197L | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DDC | c.209A>T p.H70L | Missense Mutation (SNP) | VAF 157/574 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DDX31 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 92/256 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DENND2A | c.1823T>A p.L608Q | Missense Mutation (SNP) | VAF 121/365 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMBT1 | c.4976G>A p.W1659* (on ENST00000338354 / NM_001377530.1; = p.W902* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 151/502 reads (30%) | called by muse, mutect2, varscan2
- DMRT2 | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DNAH12 | c.8830T>A p.S2944T (on ENST00000351747; = p.S3812T on NM_001366028.2) | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DNAH5 | c.4762A>T p.S1588C | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK4 | c.166A>T p.I56L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- DOCK9 | c.347A>T p.Y116F (on ENST00000376460 / NM_001366676.2; = p.Y117F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DUSP4 | c.788T>A p.I263K | Missense Mutation (SNP) | VAF 69/236 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EEA1 | c.1690A>T p.N564Y | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EFCAB9 | c.126del p.N42Kfs*3 | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | called by mutect2, pindel, varscan2
- EFR3B | c.848A>T p.Q283L | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EMILIN2 | c.797T>A p.L266* | Nonsense Mutation (SNP) | VAF 76/213 reads (36%) | called by muse, mutect2, varscan2
- ENPP4 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EP400 | c.1784A>T p.K595M | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPAS1 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EPHA10 | c.1832A>T p.H611L | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- FBXO9 | c.754A>T p.T252S | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER1L5 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 63/200 reads (32%) | called by muse, mutect2, varscan2
- FKBP6 | c.709A>T p.I237L | Missense Mutation (SNP) | VAF 144/508 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLT4 | c.1631A>T p.E544V | Missense Mutation (SNP) | VAF 173/609 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FMN1 | c.34A>T p.K12* | Nonsense Mutation (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- FN1 | c.3071T>A p.I1024K | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FOXN2 | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FOXS1 | c.77T>A p.L26H | Missense Mutation (SNP) | VAF 128/387 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM1 | c.259A>T p.N87Y | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FRMPD2 | c.3418A>T p.T1140S | Missense Mutation (SNP) | VAF 108/485 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, varscan2
- FST | c.889A>T p.M297L | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- FSTL4 | c.889A>T p.I297F | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAPVD1 | c.259A>T p.K87* | Nonsense Mutation (SNP) | VAF 49/166 reads (30%) | called by muse, mutect2, varscan2
- GAS8 | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GFI1 | c.992T>A p.L331Q | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- GJA3 | c.38A>T p.N13I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- GLUD2 | c.949_950del p.M317Efs*9 | Frame Shift Del (DEL) | VAF 91/189 reads (48%) | called by mutect2, pindel, varscan2
- GOLGA6L2 | c.329A>C p.Q110P | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- GPM6A | c.758A>T p.D253V | Missense Mutation (SNP) | VAF 116/431 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPSM1 | c.755A>T p.Y252F | Missense Mutation (SNP) | VAF 90/288 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GTF2IRD1 | c.206A>T p.K69M | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEATR5B | c.4823_4824dup p.E1609Lfs*15 | Frame Shift Ins (INS) | VAF 38/157 reads (24%) | called by mutect2, pindel, varscan2
- HOXC4 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 79/290 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HPD | c.887A>T p.Y296F | Missense Mutation (SNP) | VAF 222/688 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- HRH4 | c.1129A>T p.K377* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ICE1 | c.3371A>T p.D1124V | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IDO1 | c.438-2A>T p.X146_splice | Splice Site (SNP) | VAF 58/219 reads (26%) | called by muse, mutect2, varscan2
- IGFN1 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 45/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- IKBKB | c.266A>T p.N89I | Missense Mutation (SNP) | VAF 86/305 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ILVBL | c.689A>T p.K230M | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ISLR2 | c.1826T>A p.L609Q | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KCNH8 | c.1089T>A p.F363L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA2012 | c.2467T>A p.Y823N | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.23); called by muse, mutect2, varscan2
- KIF20B | c.3373A>C p.K1125Q (on ENST00000371728 / NM_001284259.2; = p.K1085Q on NM_016195.4) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF24 | c.1234A>T p.K412* | Nonsense Mutation (SNP) | VAF 49/144 reads (34%) | called by muse, mutect2, varscan2
- KIF5C | c.1378A>G p.R460G | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- KRT6B | c.1289T>A p.L430Q | Missense Mutation (SNP) | VAF 264/1009 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KRT79 | c.860T>A p.L287Q | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- KRTAP6-1 | c.54T>A p.C18* | Nonsense Mutation (SNP) | VAF 156/554 reads (28%) | called by muse, mutect2, varscan2
- KSR2 | c.1664A>T p.Q555L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- LCP1 | c.1641T>A p.S547R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LETM2 | c.359_362dup p.Y122Ifs*3 (on ENST00000379957 / NM_001286819.2; = p.Y75Ifs*3 on NM_144652.3) | Frame Shift Ins (INS) | VAF 100/377 reads (27%) | called by mutect2, pindel, varscan2
- LONP2 | c.1544A>T p.Q515L | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- LONRF1 | c.1993del p.Y665Ifs*34 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | called by mutect2, pindel
- MACF1 | c.614A>T p.Q205L | Missense Mutation (SNP) | VAF 71/274 reads (26%) | called by muse, mutect2, varscan2
- MAP4 | c.2321A>T p.K774M | Missense Mutation (SNP) | VAF 131/256 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARCHF6 | c.2657A>T p.Q886L | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- MDGA2 | c.2054A>T p.E685V (on ENST00000399232 / NM_001113498.2; = p.E387V on NM_182830.4) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.84); called by muse, mutect2
- MEP1A | c.234del p.I79Ffs*11 | Frame Shift Del (DEL) | VAF 45/201 reads (22%) | called by mutect2, pindel, varscan2
- MGAM2 | c.2449A>T p.K817* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- MITF | c.889A>T p.R297* (on ENST00000448226 / NM_006722.3; = p.R197* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 103/353 reads (29%) | called by muse, mutect2, varscan2
- MOGAT2 | c.298T>A p.S100T | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MPPED1 | c.292A>T p.T98S | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, varscan2
- MTPAP | c.1387-2A>T p.X463_splice | Splice Site (SNP) | VAF 68/239 reads (28%) | called by muse, mutect2, varscan2
- MYH4 | c.1378A>T p.I460F | Missense Mutation (SNP) | VAF 156/462 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO1B | c.2328A>T p.Q776H | Missense Mutation (SNP) | VAF 139/501 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO9A | c.5987A>T p.E1996V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- MYOF | c.2608A>T p.M870L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCKAP1L | c.600T>A p.A200= | Splice Region (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- NCOA1 | c.1915A>T p.T639S | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NDC80 | c.331A>T p.N111Y | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- NEB | c.11181A>T p.Q3727H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEXMIF | c.1384T>A p.Y462N | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- NLRP2 | c.1106T>A p.L369Q | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- NLRP2 | c.2708T>A p.V903E | Missense Mutation (SNP) | VAF 146/462 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NOC4L | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NOVA2 | c.1424A>T p.Q475L | Missense Mutation (SNP) | VAF 160/537 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NOX3 | c.707T>A p.L236Q | Missense Mutation (SNP) | VAF 102/332 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR1L6 | c.105A>T p.R35S | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR4Q3 | c.99del p.L35Sfs*18 | Frame Shift Del (DEL) | VAF 35/213 reads (16%) | called by mutect2, pindel, varscan2
- OR5D13 | c.222T>A p.C74* | Nonsense Mutation (SNP) | VAF 57/172 reads (33%) | called by muse, mutect2, varscan2
- OR8D4 | c.507T>A p.C169* | Nonsense Mutation (SNP) | VAF 59/218 reads (27%) | called by muse, mutect2, varscan2
- PA2G4 | c.725A>C p.Q242P | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PAK3 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 116/201 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- PBRM1 | c.2939T>A p.I980N | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.1572T>A p.Y524* | Nonsense Mutation (SNP) | VAF 133/427 reads (31%) | called by muse, mutect2, varscan2
- PCLO | c.11693A>T p.Q3898L | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PCSK5 | c.2081A>T p.E694V | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PHF3 | c.1115_1118del p.E372Vfs*5 | Frame Shift Del (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- PHLDB3 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PKD1L3 | c.146A>T p.H49L | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKP4 | c.1511A>T p.D504V | Missense Mutation (SNP) | VAF 97/327 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLA2R1 | c.3602A>G p.E1201G | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PLA2R1 | c.3601G>T p.E1201* | Nonsense Mutation (SNP) | VAF 71/238 reads (30%) | called by muse, mutect2, varscan2
- PLCH1 | c.2999-2A>T p.X1000_splice (on ENST00000340059 / NM_001130960.2; = p.X992_splice on NM_014996.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.3390T>G p.D1130E (on ENST00000283426; = p.D1486E on NM_052909.5) | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHN1 | c.170A>T p.Y57F | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- POTEH | c.971T>A p.V324E | Missense Mutation (SNP) | VAF 79/1720 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- PPIP5K1 | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 184/1220 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PRDM16 | c.1474A>T p.R492W | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PSG3 | c.161T>A p.L54H | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PTPN14 | c.1780A>T p.S594C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PTPN6 | c.380A>T p.K127M | Missense Mutation (SNP) | VAF 159/515 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PTPRB | c.4652A>T p.E1551V | Missense Mutation (SNP) | VAF 100/380 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PTPRM | c.3248A>T p.K1083M | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- R3HDM1 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated (0.93); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RASSF8 | c.942T>A p.N314K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- RASSF9 | c.995T>C p.I332T | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RBM46 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM46 | c.1135A>T p.T379S | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- REG1B | c.320A>T p.K107M | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFC2 | c.137del p.K46Sfs*2 | Frame Shift Del (DEL) | VAF 85/307 reads (28%) | called by mutect2, pindel, varscan2
- RHPN1 | c.325A>T p.M109L | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RIF1 | c.6220A>T p.S2074C | Missense Mutation (SNP) | VAF 63/198 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- RIMBP2 | c.1579T>A p.Y527N | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RNF6 | c.1898G>A p.S633N | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- RPRD1B | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RRBP1 | c.2041_2054del p.I681Afs*8 (on ENST00000377813 / NM_001365613.2; = p.I248Afs*8 on NM_004587.3) | Frame Shift Del (DEL) | VAF 30/138 reads (22%) | called by mutect2, pindel
- RRP1 | c.1267A>T p.R423W | Missense Mutation (SNP) | VAF 140/391 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RSL1D1 | c.358A>T p.K120* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- RSPH10B2 | c.614A>T p.E205V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by mutect2, varscan2
- RSPO1 | c.316T>A p.F106I | Missense Mutation (SNP) | VAF 82/310 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR2 | c.11276T>A p.L3759Q | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SAG | c.386A>T p.Y129F | Missense Mutation (SNP) | VAF 92/276 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SAMD4A | c.1093G>T p.V365F | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SH3TC2 | c.3775A>T p.N1259Y | Missense Mutation (SNP) | VAF 134/383 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHC4 | c.1649A>T p.E550V | Missense Mutation (SNP) | VAF 103/346 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SLC12A3 | c.1096-2A>T p.X366_splice | Splice Site (SNP) | VAF 30/111 reads (27%) | called by muse, varscan2
- SLC14A2 | c.572T>A p.L191Q | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SLC16A8 | c.1304T>A p.L435Q | Missense Mutation (SNP) | VAF 127/403 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC1A1 | c.1481A>G p.N494S | Missense Mutation (SNP) | VAF 126/369 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC1A6 | c.1430T>A p.V477D | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC22A11 | c.425A>C p.K142T | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC24A4 | c.1592T>A p.L531Q | Missense Mutation (SNP) | VAF 97/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A24 | c.1186A>T p.S396C | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC43A3 | c.1015A>T p.M339L | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SLC66A1L | n.355-2A>T | Splice Site (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- SLFN11 | c.2182_2183del p.T728Qfs*21 | Frame Shift Del (DEL) | VAF 101/433 reads (23%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.887del p.P296Hfs*93 | Frame Shift Del (DEL) | VAF 38/175 reads (22%) | called by mutect2, pindel, varscan2
- SMARCAD1 | c.3001A>T p.M1001L | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- SMCR8 | c.1900A>T p.N634Y | Missense Mutation (SNP) | VAF 88/297 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SORCS1 | c.2369A>T p.Q790L | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SORCS3 | c.1559A>T p.K520I | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SOS2 | c.1657G>C p.D553H | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SOS2 | c.1656A>T p.L552F | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPATA31A6 | c.1168A>T p.K390* | Nonsense Mutation (SNP) | VAF 230/462 reads (50%) | called by muse, mutect2, varscan2
- SPEM2 | c.772T>A p.Y258N | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- SPNS3 | c.200-2A>T p.X67_splice | Splice Site (SNP) | VAF 72/211 reads (34%) | called by muse, mutect2, varscan2
- ST3GAL4 | c.342-2A>T p.X114_splice (on ENST00000392669 / NM_001254758.1; = p.X110_splice on NM_006278.3) | Splice Site (SNP) | VAF 67/199 reads (34%) | called by muse, mutect2, varscan2
- STAT3 | c.1660A>T p.M554L | Missense Mutation (SNP) | VAF 126/447 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- STAT4 | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5 | c.707A>T p.Y236F | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- TAF15 | c.1310A>T p.Y437F (on ENST00000605844 / NM_139215.3; = p.Y434F on NM_003487.4) | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R60 | c.563A>T p.Y188F | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TDRD12 | c.1958A>T p.H653L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TDRD3 | c.1582A>T p.N528Y | Missense Mutation (SNP) | VAF 79/266 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TMC8 | c.1522T>A p.Y508N | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TMEM156 | c.747A>T p.R249S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM259 | c.1316A>T p.Q439L | Missense Mutation (SNP) | VAF 98/284 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TMEM26 | c.187A>T p.K63* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- TNR | c.2465T>A p.L822Q | Missense Mutation (SNP) | VAF 76/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX4 | c.203del p.S68Yfs*21 | Frame Shift Del (DEL) | VAF 78/286 reads (27%) | called by mutect2, pindel*, varscan2
- TPTE2 | c.307T>A p.Y103N (on ENST00000400230 / NM_199254.2; = p.Y66N on NM_130785.3) | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TRPM6 | c.1684A>T p.T562S | Missense Mutation (SNP) | VAF 137/472 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TSGA10IP | c.188T>A p.L63Q | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TTN | c.73344T>A p.C24448* (on ENST00000591111; = p.C17024* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 76/263 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.28167T>A p.S9389R (on ENST00000591111; = p.S8462R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/134 reads (23%) | PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TTYH1 | c.718A>C p.K240Q | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- TWIST1 | c.241T>A p.C81S | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR4 | c.1534A>T p.M512L | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- UEVLD | c.494-2A>T p.X165_splice | Splice Site (SNP) | VAF 37/115 reads (32%) | called by muse, mutect2, varscan2
- ULK4 | c.3085A>T p.S1029C | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- USP34 | c.5975A>C p.E1992A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- USP50 | c.511A>T p.T171S (on ENST00000616326; = p.T162S on NM_203494.5) | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS53 | c.545T>A p.M182K (on ENST00000571805 / NM_001366253.2; = p.M153K on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- VSIG10L | c.2438A>G p.K813R | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- VWA8 | c.2830G>C p.G944R | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR19 | c.1538A>T p.H513L | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZFP30 | c.851A>T p.H284L | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZIC3 | c.1163A>T p.Y388F | Missense Mutation (SNP) | VAF 103/152 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF134 | c.1256A>T p.Q419L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF292 | c.5039dup p.S1681Efs*12 | Frame Shift Ins (INS) | VAF 44/194 reads (23%) | called by mutect2, pindel, varscan2
- ZNF804A | c.3383A>T p.H1128L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZNF845 | c.1067A>T p.K356I | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADGRV1 | c.8850T>A p.V2950= | Silent (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- AK9 | c.2478C>T p.P826= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs958543521, COSV58139097, COSV58140680; called by muse, mutect2, varscan2
- ANK3 | c.9240A>T p.L3080= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- ATP12A | c.1407T>A p.T469= | Silent (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- BBS9 | c.2568A>T p.V856= (on ENST00000242067 / NM_001348036.1; = p.V816= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 103/341 reads (30%) | called by muse, mutect2, varscan2
- BMP5 | c.585A>T p.A195= | Silent (SNP) | VAF 77/280 reads (28%) | called by muse, mutect2, varscan2
- CA4 | c.423A>T p.I141= | Silent (SNP) | VAF 69/264 reads (26%) | called by muse, mutect2, varscan2
- CBLB | c.2028A>T p.P676= | Silent (SNP) | VAF 83/230 reads (36%) | called by muse, mutect2, varscan2
- CD48 | c.201A>G p.V67= | Silent (SNP) | VAF 58/183 reads (32%) | called by muse, mutect2, varscan2
- CHD9 | c.2139A>T p.T713= | Silent (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- CSMD3 | c.384T>A p.P128= | Silent (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
- CTTN | c.372G>A p.K124= | Silent (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2, varscan2
- CYYR1 | c.207A>T p.G69= | Silent (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- DNAI3 | c.1410A>T p.A470= | Silent (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- DPY19L4 | c.174A>T p.A58= | Silent (SNP) | VAF 74/232 reads (32%) | called by muse, mutect2, varscan2
- EDAR | c.255G>A p.Q85= | Silent (SNP) | VAF 180/512 reads (35%) | called by muse, mutect2, varscan2
- EIF3D | c.1365C>T p.Y455= | Silent (SNP) | VAF 42/116 reads (36%) | called by muse, mutect2
- EN1 | c.747T>A p.A249= | Silent (SNP) | VAF 188/626 reads (30%) | catalogued as COSV54632024; called by muse, mutect2, varscan2
- EPS15 | c.2307A>T p.P769= | Silent (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- FAM13C | c.78A>T p.P26= | Silent (SNP) | VAF 80/276 reads (29%) | called by muse, mutect2, varscan2
- FAM193B | c.1983T>A p.V661= | Silent (SNP) | VAF 35/136 reads (26%) | called by muse, mutect2, varscan2
- FANCM | c.3942A>T p.A1314= | Silent (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- GCG | c.474T>A p.I158= | Silent (SNP) | VAF 75/317 reads (24%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.2028A>T p.G676= | Silent (SNP) | VAF 153/661 reads (23%) | called by muse, mutect2, varscan2
- GPR84 | c.438T>A p.V146= | Silent (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
- HERC2 | c.2172G>C p.L724= | Silent (SNP) | VAF 13/195 reads (7%) | catalogued as COSV55341197; called by muse, mutect2
- IL20RA | c.1308A>T p.A436= | Silent (SNP) | VAF 56/177 reads (32%) | called by muse, mutect2, varscan2
- ITFG1 | c.594A>T p.T198= | Silent (SNP) | VAF 76/239 reads (32%) | called by muse, mutect2, varscan2
- KCNJ5 | c.1152A>T p.P384= | Silent (SNP) | VAF 48/150 reads (32%) | called by muse, mutect2, varscan2
- KIF23 | c.489A>T p.I163= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV99532190; called by muse, mutect2, varscan2
- KRTAP4-1 | c.57C>A p.L19= | Silent (SNP) | VAF 101/299 reads (34%) | called by muse, mutect2, varscan2
- LAMA5 | c.4329A>T p.V1443= | Silent (SNP) | VAF 53/172 reads (31%) | called by muse, mutect2, varscan2
- MBD5 | c.4395G>A p.L1465= | Silent (SNP) | VAF 76/302 reads (25%) | called by muse, mutect2, varscan2
- MIA2 | c.1422C>T p.L474= | Silent (SNP) | VAF 8/195 reads (4%) | called by muse, mutect2
- MPPED1 | c.348T>A p.A116= | Silent (SNP) | VAF 71/221 reads (32%) | called by muse, varscan2
- MRPS17 | c.267A>G p.G89= | Silent (SNP) | VAF 132/449 reads (29%) | called by muse, mutect2, varscan2
- MYH4 | c.1035T>A p.T345= | Silent (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- OR2W1 | c.264T>C p.P88= | Silent (SNP) | VAF 72/187 reads (39%) | catalogued as rs768470592; called by muse, mutect2, varscan2
- OR6M1 | c.381A>T p.P127= | Silent (SNP) | VAF 26/103 reads (25%) | called by muse, mutect2, varscan2
- OTC | c.456T>A p.A152= | Silent (SNP) | VAF 116/167 reads (69%) | called by muse, mutect2, varscan2
- PCDH15 | c.711T>C p.R237= | Silent (SNP) | VAF 142/545 reads (26%) | called by muse, mutect2
- PEAR1 | c.2088T>A p.P696= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1221A>T p.L407= | Silent (SNP) | VAF 16/57 reads (28%) | called by muse, mutect2, varscan2
- PNPLA1 | c.1569A>T p.G523= (on ENST00000394571 / NM_001374623.1; = p.G428= on NM_173676.2) | Silent (SNP) | VAF 40/132 reads (30%) | called by muse, mutect2, varscan2
- PRR12 | c.2304C>T p.S768= (on ENST00000615927; = p.S1589= on NM_020719.3) | Silent (SNP) | VAF 90/316 reads (28%) | catalogued as rs991519777; called by muse, mutect2, varscan2
- PSG1 | c.891A>T p.L297= | Silent (SNP) | VAF 113/451 reads (25%) | called by muse, mutect2, varscan2
- RBM48 | c.150A>T p.I50= | Silent (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- RNF17 | c.2586A>T p.L862= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- RNMT | c.774A>T p.I258= | Silent (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- RP1L1 | c.378T>A p.A126= | Silent (SNP) | VAF 39/152 reads (26%) | called by muse, mutect2, varscan2
- RPA1 | c.279A>T p.V93= | Silent (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- SETD1B | c.4782A>T p.P1594= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- SKIV2L | c.780A>T p.L260= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- SLC35G3 | c.150T>A p.P50= | Silent (SNP) | VAF 119/371 reads (32%) | called by muse, mutect2, varscan2
- SLC39A12 | c.729T>G p.R243= | Silent (SNP) | VAF 58/206 reads (28%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1491T>A p.P497= | Silent (SNP) | VAF 90/299 reads (30%) | called by muse, mutect2, varscan2
- SPATA5 | c.1281C>T p.F427= | Silent (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- SPTA1 | c.2514C>T p.I838= | Silent (SNP) | VAF 193/599 reads (32%) | called by muse, mutect2, varscan2
- STAC2 | c.975T>A p.S325= | Silent (SNP) | VAF 65/243 reads (27%) | called by muse, mutect2, varscan2
- TMEM177 | c.876C>T p.T292= | Silent (SNP) | VAF 44/168 reads (26%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.747C>T p.P249= | Silent (SNP) | VAF 130/477 reads (27%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.3048A>T p.P1016= | Silent (SNP) | VAF 80/261 reads (31%) | called by muse, mutect2, varscan2
- TRBV20-1 | c.135A>T p.T45= | Silent (SNP) | VAF 88/301 reads (29%) | called by muse, mutect2, varscan2
- TREML2 | c.528T>G p.P176= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- TTC17 | c.594A>T p.T198= | Silent (SNP) | VAF 54/179 reads (30%) | called by muse, mutect2, varscan2
- TTI1 | c.255A>T p.T85= | Silent (SNP) | VAF 80/259 reads (31%) | called by muse, mutect2, varscan2
- TTLL5 | c.2814A>T p.T938= | Silent (SNP) | VAF 126/400 reads (32%) | called by muse, mutect2, varscan2
- WNT1 | c.36T>A p.S12= | Silent (SNP) | VAF 69/258 reads (27%) | called by muse, mutect2, varscan2
- XIRP2 | c.6120A>T p.V2040= (on ENST00000628543; = p.V2215= on NM_152381.6) | Silent (SNP) | VAF 69/276 reads (25%) | called by muse, mutect2, varscan2
- ZBBX | c.450A>T p.G150= | Silent (SNP) | VAF 59/179 reads (33%) | called by muse, mutect2, varscan2
- ZMAT1 | c.1359A>T p.S453= | Silent (SNP) | VAF 29/43 reads (67%) | called by muse, mutect2, varscan2
- AADAC | c.-35T>A | 5'UTR (SNP) | VAF 79/282 reads (28%) | called by muse, mutect2, varscan2
- AC009053.1 | n.686A>T | RNA (SNP) | VAF 104/695 reads (15%) | called by muse, varscan2
- AC010507.1 | chr19:200767 C>T | 3'Flank (SNP) | VAF 4/251 reads (2%) | catalogued as rs752589210; called by muse, mutect2
- AC011330.1 | n.856A>T | RNA (SNP) | VAF 17/97 reads (18%) | called by mutect2, varscan2
- AC024940.1 | n.2480T>A | RNA (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- AC044798.1 | n.131T>A | RNA (SNP) | VAF 40/155 reads (26%) | called by muse, mutect2, varscan2
- AC116655.1 | n.173A>C | RNA (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- AC120036.1 | n.104+7856A>T | Intron (SNP) | VAF 85/335 reads (25%) | called by muse, mutect2, varscan2
- ACAD10 | c.*196C>T | 3'UTR (SNP) | VAF 62/168 reads (37%) | called by muse, mutect2, varscan2
- ACTB | c.-27-26A>T | Intron (SNP) | VAF 116/327 reads (35%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38775A>T | Intron (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- AQP6 | c.*1319C>T | 3'UTR (SNP) | VAF 45/151 reads (30%) | catalogued as rs1173790927; called by muse, mutect2, varscan2
- ASB10 | chr7:151187517 T>A | 5'Flank (SNP) | VAF 110/413 reads (27%) | called by muse, mutect2, varscan2
- CAPN1 | chr11:65214117 A>T | 3'Flank (SNP) | VAF 83/292 reads (28%) | called by muse, mutect2, varscan2
- CLRN1 | c.*1015C>T | 3'UTR (SNP) | VAF 136/452 reads (30%) | called by muse, mutect2, varscan2
- CSF3R | c.2041-10T>A | Intron (SNP) | VAF 78/237 reads (33%) | called by muse, mutect2, varscan2
- DCHS2 | n.3856A>T | RNA (SNP) | VAF 80/245 reads (33%) | called by muse, mutect2
- DCHS2 | n.3854G>A | RNA (SNP) | VAF 82/252 reads (33%) | called by muse, mutect2
- DIO3OS | chr14:101552476 T>A | 3'Flank (SNP) | VAF 86/275 reads (31%) | called by muse, mutect2, varscan2
- DLG1 | c.483+10777A>T | Intron (SNP) | VAF 86/322 reads (27%) | called by muse, mutect2, varscan2
- EFCAB5 | c.2738-5080A>T | Intron (SNP) | VAF 57/225 reads (25%) | catalogued as rs1288458499; called by muse, mutect2, varscan2
- FMN1 | c.2044-1645A>T | Intron (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- GDAP1L1 | c.*482T>A | 3'UTR (SNP) | VAF 58/175 reads (33%) | called by muse, mutect2, varscan2
- GSG1L2 | c.311-18A>T | Intron (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1182A>T | RNA (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- KCNMA1 | c.378+680C>T | Intron (SNP) | VAF 98/321 reads (31%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.584T>A | RNA (SNP) | VAF 94/249 reads (38%) | called by muse, mutect2, varscan2
- LINC02145 | n.405G>A | RNA (SNP) | VAF 32/110 reads (29%) | catalogued as rs770611459; called by muse, mutect2
- LINC02272 | n.336C>T | RNA (SNP) | VAF 31/125 reads (25%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11801A>C | Intron (SNP) | VAF 79/288 reads (27%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-9623C>G | Intron (SNP) | VAF 122/392 reads (31%) | catalogued as rs940838984; called by muse, mutect2, varscan2
- MIR516A2 | n.42T>A | RNA (SNP) | VAF 31/105 reads (30%) | catalogued as rs756888245; called by muse, mutect2, varscan2
- MLXIP | c.2509-78A>T | Intron (SNP) | VAF 91/294 reads (31%) | called by muse, mutect2, varscan2
- MORF4 | n.697T>A | RNA (SNP) | VAF 99/322 reads (31%) | called by muse, mutect2, varscan2
- MTHFD1 | c.-161A>T | 5'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- MTRNR2L6 | chr7:142671002 A>T | 3'Flank (SNP) | VAF 55/170 reads (32%) | called by muse, mutect2, varscan2
- NETO1 | c.469+23529A>T | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- NPS | c.-4del | 5'UTR (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- OSBPL2 | chr20:62232939 T>A | 5'Flank (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- PLK5 | c.-29A>T | 5'UTR (SNP) | VAF 52/194 reads (27%) | called by muse, mutect2
- PTPN22 | c.88-4806A>C | Intron (SNP) | VAF 60/206 reads (29%) | called by muse, mutect2, varscan2
- RBBP8 | c.248+31A>T | Intron (SNP) | VAF 29/93 reads (31%) | called by muse, mutect2, varscan2
- SNCA | c.*18A>T | 3'UTR (SNP) | VAF 103/310 reads (33%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2471A>T | RNA (SNP) | VAF 259/798 reads (32%) | called by muse, mutect2, varscan2
- SRL | c.62-3294A>T | Intron (SNP) | VAF 72/250 reads (29%) | called by muse, mutect2, varscan2
- TAFA2 | c.*39T>A | 3'UTR (SNP) | VAF 46/144 reads (32%) | called by muse, mutect2, varscan2
- TMEM135 | c.*6615A>T | 3'UTR (SNP) | VAF 220/654 reads (34%) | called by mutect2, varscan2
- TOGARAM2 | c.2722+104C>T | Intron (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- TPRXL | n.734A>T | RNA (SNP) | VAF 70/158 reads (44%) | called by muse, mutect2, varscan2
- TTN | c.10360+5421A>T | Intron (SNP) | VAF 92/311 reads (30%) | called by muse, mutect2, varscan2
- VPS35 | c.914+41G>T | Intron (SNP) | VAF 84/278 reads (30%) | called by muse, mutect2, varscan2
- WDR53 | c.-367T>G | 5'UTR (SNP) | VAF 42/127 reads (33%) | catalogued as rs1228509758; called by muse, mutect2, varscan2
- YPEL1 | c.118-10C>G | Intron (SNP) | VAF 26/129 reads (20%) | catalogued as rs766360593; called by muse, mutect2, varscan2
- Y_RNA | chr7:75512609 T>A | 3'Flank (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- ZNF407 | c.5428+12A>T | Intron (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
